Somatic mutation profile of tumor specimen 0DJHH5 from CCDI case PBBWKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.5 years (3,468 days).
Specimen 0DJHH5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ced9aeb6-b6b1-400f-8f67-bed9e3ad8b69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHDZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ea9036e-6341-4202-9f0a-e961f35ee0eb

The open-access MAF lists 82 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 19, Intron 8, 5'UTR 4, Nonsense Mutation 3, 3'UTR 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 396/473 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH15 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.916); catalogued as rs762117025; called by muse, mutect2, varscan2
- CFAP221 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 129/832 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV54654763; called by muse, mutect2, varscan2
- CFAP54 | c.6389C>A p.A2130D | Missense Mutation (SNP) | VAF 66/479 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774295685, COSV100733315; called by muse, mutect2, varscan2
- CYP4F12 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 195/959 reads (20%) | catalogued as COSV61175560; called by muse, mutect2, varscan2
- DCSTAMP | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 256/1333 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV99886903, COSV99886906; called by muse, mutect2, varscan2
- GYS1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs370035815; called by muse, mutect2, varscan2
- ITM2C | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 202/331 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146175008; called by muse, mutect2, varscan2
- KIAA1210 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 110/151 reads (73%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs763902237, COSV68180882; called by muse, mutect2, varscan2
- LYPD4 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 101/424 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV58027577; called by muse, mutect2, varscan2
- MIA2 | c.2176G>T p.A726S | Missense Mutation (SNP) | VAF 140/546 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756757586, COSV54499036; called by mutect2, varscan2
- OR5M11 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 380/958 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372489507, COSV101602010, COSV73141686; called by muse, mutect2, varscan2
- OR9Q2 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 221/1392 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs746060364, COSV61111404; called by muse, mutect2, varscan2
- ORAI2 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 98/306 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs766937231, COSV100709903; called by muse, mutect2, varscan2
- PCNX3 | c.2459G>T p.W820L | Missense Mutation (SNP) | VAF 263/775 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV63139487; called by muse, mutect2, varscan2
- RAB11FIP4 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 265/300 reads (88%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.902); catalogued as rs913536456, COSV57926560; called by muse, mutect2, varscan2
- SENP6 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 215/588 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as rs1450596753, COSV100894261; called by muse, mutect2, varscan2
- SPATA31D1 | c.3034C>T p.L1012F | Missense Mutation (SNP) | VAF 182/467 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs893457893, COSV61196904; called by muse, mutect2, varscan2
- STAG3 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 197/804 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1245101137, COSV57936077; called by muse, mutect2, varscan2
- TYR | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 54/1052 reads (5%) | catalogued as CM100975, COSV54479427; called by muse, mutect2
- ZC3H13 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 110/712 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs777308536, COSV54457064; called by muse, mutect2, varscan2
- ALPG | c.469A>T p.K157* | Nonsense Mutation (SNP) | VAF 60/509 reads (12%) | called by muse, mutect2, varscan2
- APOB | c.9632dup p.N3211Kfs*14 | Frame Shift Ins (INS) | VAF 322/1064 reads (30%) | called by mutect2, varscan2
- ATP10B | c.873T>G p.H291Q | Missense Mutation (SNP) | VAF 15/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- C9orf43 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 225/468 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- CKB | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 104/322 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CPSF1 | c.3314C>T p.T1105I | Missense Mutation (SNP) | VAF 84/464 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CSNK1G3 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 120/721 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DCBLD2 | c.1990C>T p.H664Y | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EIF3E | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 458/1092 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GPR162 | c.1377A>C p.R459S (on ENST00000311268 / NM_019858.2; = p.R175S on NM_014449.2) | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ITK | c.1246C>G p.P416A | Missense Mutation (SNP) | VAF 126/661 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ITPR1 | c.7520C>T p.S2507F (on ENST00000354582; = p.S2452F on NM_002222.7) | Missense Mutation (SNP) | VAF 177/358 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- KCNB2 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 235/853 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNN3 | c.1176C>A p.F392L | Missense Mutation (SNP) | VAF 126/269 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT2D | c.8110A>G p.K2704E | Missense Mutation (SNP) | VAF 80/488 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LINGO3 | c.437T>C p.F146S | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAST1 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 60/978 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- OR2J1 | c.55T>G p.S19A | Missense Mutation (SNP) | VAF 61/578 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCDHA1 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 101/419 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SYNE2 | c.11051C>A p.P3684Q | Missense Mutation (SNP) | VAF 244/860 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TATDN1 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 496/1165 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFB1M | c.183A>T p.E61D | Missense Mutation (SNP) | VAF 50/680 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TIMM44 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- TRIM66 | c.2733C>A p.S911R | Missense Mutation (SNP) | VAF 334/942 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by mutect2, varscan2
- UNC80 | c.7177G>T p.A2393S | Missense Mutation (SNP) | VAF 275/812 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- XKR9 | c.754C>A p.Q252K | Missense Mutation (SNP) | VAF 138/578 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF256 | c.1298G>C p.R433T | Missense Mutation (SNP) | VAF 220/831 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1B | c.3846C>T p.V1282= | Silent (SNP) | VAF 199/483 reads (41%) | called by muse, mutect2, varscan2
- CHST15 | c.42C>T p.D14= | Silent (SNP) | VAF 96/587 reads (16%) | catalogued as rs369700369; called by muse, mutect2, varscan2
- COL13A1 | c.981C>A p.G327= (on ENST00000398978 / NM_001130103.2; = p.G270= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/232 reads (30%) | called by muse, mutect2, varscan2
- DOK3 | c.241C>T p.L81= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as COSV100394549; called by muse, mutect2, varscan2
- EXOC5 | c.1233A>G p.L411= | Silent (SNP) | VAF 68/659 reads (10%) | catalogued as rs757124500; called by muse, mutect2, varscan2
- KYAT3 | c.663C>A p.G221= | Silent (SNP) | VAF 24/684 reads (4%) | called by muse, mutect2
- LRRC37A3 | c.4845A>G p.E1615= | Silent (SNP) | VAF 76/968 reads (8%) | called by muse, mutect2
- MAPK8IP2 | c.1680G>T p.S560= | Silent (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- OR10G3 | c.834G>A p.T278= | Silent (SNP) | VAF 107/358 reads (30%) | catalogued as rs753769969; called by muse, mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 11/292 reads (4%) | called by muse, mutect2
- OSGIN2 | c.1296G>A p.K432= | Silent (SNP) | VAF 259/1136 reads (23%) | called by muse, mutect2, varscan2
- PARP2 | c.948T>C p.R316= | Silent (SNP) | VAF 105/439 reads (24%) | catalogued as rs1162163358; called by muse, mutect2, varscan2
- PCDHB3 | c.357C>T p.N119= | Silent (SNP) | VAF 219/1078 reads (20%) | catalogued as COSV50565975; called by muse, mutect2, varscan2
- RMDN2 | c.177T>C p.H59= | Silent (SNP) | VAF 153/1155 reads (13%) | called by muse, mutect2, varscan2
- RNF214 | c.145C>T p.L49= | Silent (SNP) | VAF 155/911 reads (17%) | called by muse, mutect2, varscan2
- RUFY2 | c.1752T>C p.C584= | Silent (SNP) | VAF 237/634 reads (37%) | called by muse, mutect2, varscan2
- STARD13 | c.3135G>A p.V1045= (on ENST00000336934 / NM_001243476.3; = p.V927= on NM_052851.3) | Silent (SNP) | VAF 121/1135 reads (11%) | called by muse, mutect2, varscan2
- TMEM151A | c.687G>C p.A229= | Silent (SNP) | VAF 79/391 reads (20%) | called by muse, mutect2, varscan2
- ZHX2 | c.1503C>A p.I501= | Silent (SNP) | VAF 67/751 reads (9%) | called by muse, mutect2
- ADCK2 | c.*55C>T | 3'UTR (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- CAPN1 | c.843+59G>A | Intron (SNP) | VAF 13/266 reads (5%) | catalogued as rs1359017752; called by muse, mutect2
- COLEC11 | c.130+1748_130+1749insA | Intron (INS) | VAF 149/424 reads (35%) | called by mutect2, pindel, varscan2
- LILRA4 | c.35-74C>T | Intron (SNP) | VAF 55/179 reads (31%) | called by muse, mutect2, varscan2
- MAPKAP1 | c.*42G>T | 3'UTR (SNP) | VAF 103/200 reads (52%) | called by mutect2, varscan2
- MRPS11 | c.183-37G>T | Intron (SNP) | VAF 66/139 reads (47%) | called by muse, mutect2, varscan2
- NUPR2 | c.-84C>G | 5'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- OTOP1 | c.*18C>A | 3'UTR (SNP) | VAF 119/274 reads (43%) | catalogued as rs1466497828; called by muse, mutect2, varscan2
- OXGR1 | c.-2C>T | 5'UTR (SNP) | VAF 106/1356 reads (8%) | catalogued as COSV100036882; called by muse, mutect2
- PCDHGC5 | c.2460+191G>A | Intron (SNP) | VAF 18/427 reads (4%) | called by muse, mutect2
- PRR4 | c.*18+37C>G | Intron (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- RFK | c.337+82C>T | Intron (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2
- TMEM134 | c.451+100T>C | Intron (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- TSBP1 | c.-29C>T | 5'UTR (SNP) | VAF 105/284 reads (37%) | catalogued as rs757871279, COSV100898935; called by muse, mutect2, varscan2
- VPS11 | c.-1041G>T | 5'UTR (SNP) | VAF 372/1027 reads (36%) | called by muse, mutect2, varscan2
